Somatic mutation profile of tumor specimen BA2100D (aliquot aq-BA2100D) from BEATAML1.0 case 2485, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.2 years (26,734 days).
Specimen BA2100D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad944194-7ab1-4531-897f-19bcf751e822.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2404D (Solid Tissue Normal), aliquot aq-BA2404D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e936740-a2d0-45e3-b3d4-82a0e489c5b2

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HTR7 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 7/121 reads (6%) | catalogued as COSV53291179; called by muse, mutect2
- OAS3 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1185911165; called by muse, mutect2
- CAPN5 | c.451C>G p.P151A (on ENST00000456580; = p.P111A on NM_004055.5) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- CBLB | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MON1B | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- PTPRS | c.2680G>A p.G894S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SULF2 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP9X | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- OTOP2 | c.864C>A p.T288= | Silent (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- ZNF8 | c.66+65C>G | Intron (SNP) | VAF 31/110 reads (28%) | catalogued as rs777033411; called by muse, mutect2, varscan2
